Somatic mutation profile of tumor specimen TCGA-XV-A9W5-01A (aliquot TCGA-XV-A9W5-01A-11D-A38G-08) from TCGA case TCGA-XV-A9W5, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 51.3 years (18,739 days).
Specimen TCGA-XV-A9W5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6de1eab-ca2b-484f-a79b-080bb4adaa61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XV-A9W5-10A (Blood Derived Normal), aliquot TCGA-XV-A9W5-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9a9f533-ac0a-4c08-8322-266a4d884cec

The open-access MAF lists 118 somatic variants for this specimen: 69 protein-altering or splice-affecting, 46 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 46, Nonsense Mutation 3, Splice Site 2, RNA 1, Intron 1, 3'UTR 1, Frame Shift Del 1, Splice Region 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/80 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACBD7 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100650402; called by muse, mutect2, varscan2
- AGAP2 | c.1583G>A p.G528E (on ENST00000547588 / NM_001122772.2; = p.G192E on NM_014770.4) | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.61); PolyPhen benign (0.033); catalogued as COSV99222580; called by muse, mutect2, varscan2
- ARFGAP1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100796656; called by muse, mutect2, varscan2
- BCLAF1 | c.430T>G p.S144A | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV100786493; called by muse, mutect2, varscan2
- C9orf135 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV101019762; called by muse, mutect2, varscan2
- CACNA1C | c.4624C>T p.R1542C | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV59697521; called by muse, mutect2, varscan2
- CACNA2D3 | c.2908G>A p.D970N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as COSV55525116, COSV99871614; called by muse, mutect2, varscan2
- CD163 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs748750295, COSV63133563; called by muse, mutect2, varscan2
- CDH10 | c.1072C>A p.R358S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV52572321; called by muse, mutect2, varscan2
- CDK7 | c.890A>T p.N297I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99841590; called by muse, mutect2, varscan2
- CELA3B | c.632C>T p.S211F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs749455829, COSV100448637; called by muse, mutect2, varscan2
- CFAP251 | c.1643C>T p.S548F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99995850; called by muse, mutect2, varscan2
- CFHR4 | c.1591G>A p.G531R (on ENST00000367416 / NM_001201551.2; = p.G285R on NM_006684.5) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.482); catalogued as COSV52226308; called by muse, mutect2, varscan2
- CFTR | c.4328C>T p.P1443L | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV99134637; called by muse, mutect2, varscan2
- COL15A1 | c.1915G>A p.D639N | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as COSV100897526; called by muse, mutect2, varscan2
- COL3A1 | c.4211G>A p.G1404E | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58590417; called by muse, mutect2, varscan2
- COL5A1 | c.4154C>T p.P1385L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1418421771, COSV65672564; called by muse, mutect2, varscan2
- CPNE4 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV70193735; called by muse, mutect2, varscan2
- CSMD3 | c.5324C>T p.S1775L (on ENST00000297405 / NM_001363185.1; = p.S1671L on NM_052900.3) | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV52262886, COSV99828719; called by muse, mutect2, varscan2
- CYP4F8 | c.773G>T p.R258M | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV100358057; called by muse, varscan2
- DDI1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100158392; called by muse, mutect2, varscan2
- DOCK11 | c.4708C>T p.P1570S | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as rs1239526506, COSV99353252; called by muse, mutect2, varscan2
- EML3 | c.1825C>A p.Q609K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV99604123; called by muse, mutect2, varscan2
- ENPEP | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs142911369; called by muse, varscan2
- FNIP1 | c.2558C>T p.P853L | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100330326; called by muse, mutect2, varscan2
- FRAS1 | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs376133490, COSV53644633; called by muse, mutect2, varscan2
- KALRN | c.6609G>T p.R2203S (on ENST00000360013 / NM_001024660.4; = p.R506S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.012); catalogued as COSV99361458; called by muse, mutect2, varscan2
- KCTD16 | c.1279C>T p.H427Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV101568759; called by muse, mutect2, varscan2
- KDM5A | c.3316G>A p.D1106N | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.023); catalogued as COSV66995256; called by muse, mutect2, varscan2
- KLHL4 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs190477338, COSV64139169; called by muse, mutect2, varscan2
- KRT34 | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs149921426, COSV101222582; called by muse, mutect2, varscan2
- LARP1B | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.075); catalogued as COSV99217945; called by muse, mutect2, varscan2
- LRP2 | c.12967C>T p.Q4323* | Nonsense Mutation (SNP) | VAF 13/47 reads (28%) | catalogued as COSV99787199; called by muse, mutect2, varscan2
- LTBP1 | c.680C>T p.S227L | Missense Mutation (SNP) | VAF 68/195 reads (35%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs377541507; called by muse, mutect2, varscan2
- MPDZ | c.4807A>G p.N1603D | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV100056376; called by muse, mutect2, varscan2
- MUC16 | c.12881C>T p.S4294F | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.223); catalogued as COSV67455835; called by muse, mutect2, varscan2
- MYOM1 | c.4091T>A p.L1364* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV99865854; called by muse, mutect2
- NCOR2 | c.6670C>T p.P2224S | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100657037, COSV62301887; called by muse, mutect2, varscan2
- NOTCH4 | c.1185G>A p.M395I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1382478531, COSV100900497; called by muse, mutect2, varscan2
- NPTX2 | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs770355969, COSV99674762; called by muse, mutect2, varscan2
- NWD1 | c.4284C>A p.Y1428* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100342035; called by muse, mutect2, varscan2
- OR2F2 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 55/315 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101283803; called by muse, mutect2, varscan2
- OR4B1 | c.209G>A p.S70N | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1340132964, COSV58882602; called by muse, mutect2, varscan2
- OR5D16 | c.858G>C p.L286F | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV101003878, COSV65721651; called by muse, mutect2, varscan2
- OVCH2 | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.55); PolyPhen benign (0.025); catalogued as COSV101491866; called by muse, mutect2, varscan2
- PAM | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV99173174; called by muse, mutect2, varscan2
- PDE6A | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as rs746482403, COSV99678013; called by muse, mutect2
- PDIA2 | c.135G>C p.L45F | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99249470; called by muse, mutect2, varscan2
- PEBP1 | c.236C>T p.P79L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99731842; called by muse, mutect2
- PLCB4 | c.3462G>A p.A1154= (on ENST00000278655 / NM_182797.3; = p.E1167K on NM_000933.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 10/49 reads (20%) | catalogued as rs761885301, COSV53800025; called by muse, mutect2, varscan2
- POLR3B | c.1666G>C p.V556L | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV99943206; called by muse, mutect2, varscan2
- PRSS36 | c.2289+1G>A p.X763_splice | Splice Site (SNP) | VAF 6/45 reads (13%) | catalogued as rs1171874584, COSV99191241; called by muse, mutect2, varscan2
- PTPRT | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100626066; called by muse, mutect2, varscan2
- RASGRP4 | c.1997C>T p.T666I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV99384900; called by muse, mutect2, varscan2
- SEC14L5 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.41); catalogued as COSV99228677; called by muse, varscan2
- SEH1L | c.440T>C p.V147A | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as COSV100039895; called by muse, mutect2, varscan2
- SPTA1 | c.4312G>A p.D1438N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.83); catalogued as rs568705471, COSV63751684; called by muse, mutect2, varscan2
- TENM4 | c.4910G>T p.G1637V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as COSV99572528; called by muse, mutect2, varscan2
- TENM4 | c.4540G>C p.D1514H | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53652380; called by muse, mutect2
- TMC7 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs1215634897, COSV58588559; called by muse, mutect2, varscan2
- TTLL10 | c.1234G>A p.D412N (on ENST00000379289 / NM_001130045.2; = p.D339N on NM_153254.3) | Missense Mutation (SNP) | VAF 77/186 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.403); catalogued as rs372449382; called by muse, mutect2, varscan2
- TTN | c.51884G>A p.R17295Q (on ENST00000591111; = p.R9871Q on NM_003319.4) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | PolyPhen possibly damaging (0.889); catalogued as rs745914315, COSV60199761; ClinVar: likely benign; called by muse, mutect2, varscan2
- WIF1 | c.922+1G>A p.X308_splice | Splice Site (SNP) | VAF 19/40 reads (48%) | catalogued as rs1385882260, COSV54137285; called by muse, mutect2, varscan2
- XDH | c.2174C>T p.S725F | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.153); catalogued as COSV101052114; called by muse, mutect2, varscan2
- ZFHX4 | c.9637G>A p.E3213K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.686); catalogued as rs536201184, COSV51467050; called by muse, mutect2, varscan2
- ZNF585A | c.1226C>T p.S409L (on ENST00000292841 / NM_001288800.2; = p.S354L on NM_152655.3) | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs146470162; called by muse, mutect2, varscan2
- PTEN | c.240_241del p.K80Nfs*2 | Frame Shift Del (DEL) | VAF 25/49 reads (51%) | called by mutect2, pindel, varscan2
- TRAV18 | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALPK2 | c.4884G>A p.E1628= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100864208; called by muse, mutect2, varscan2
- BMP4 | c.1173G>A p.K391= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV99816829; called by muse, mutect2, varscan2
- CLTCL1 | c.2226G>A p.K742= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs782074167, COSV99594711; called by muse, mutect2, varscan2
- CMKLR1 | c.1044C>A p.P348= (on ENST00000312143 / NM_001142344.2; = p.P346= on NM_004072.3) | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs199555321, COSV100379250; called by muse, mutect2, varscan2
- CYP4F8 | c.654C>A p.P218= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100358056; called by muse, varscan2
- EGFLAM | c.108G>A p.G36= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV100470377; called by muse, mutect2
- ENPEP | c.2055G>A p.R685= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV54449962, COSV99487852; called by muse, mutect2, varscan2
- EP400 | c.2112C>T p.S704= | Silent (SNP) | VAF 35/108 reads (32%) | catalogued as COSV57769374; called by muse, mutect2, varscan2
- GABBR2 | c.516C>T p.F172= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99409541, COSV99411480; called by muse, mutect2, varscan2
- GOLGA4 | c.4629C>T p.S1543= | Silent (SNP) | VAF 31/93 reads (33%) | catalogued as rs191121471, COSV62711647; called by muse, mutect2, varscan2
- GRIK3 | c.2166C>T p.N722= | Silent (SNP) | VAF 34/92 reads (37%) | catalogued as rs373589381; called by muse, mutect2, varscan2
- HAO2 | c.525G>A p.R175= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs1366524316, COSV58039427; called by muse, mutect2, varscan2
- IL36G | c.319C>T p.L107= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV99381105; called by muse, mutect2, varscan2
- KDM5A | c.3315G>A p.L1105= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as COSV101238673; called by muse, mutect2, varscan2
- KRT33A | c.423C>T p.F141= | Silent (SNP) | VAF 18/58 reads (31%) | catalogued as COSV99144807; called by muse, mutect2, varscan2
- LRP1B | c.744T>C p.C248= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV101254294; called by muse, mutect2, varscan2
- MAN1A1 | c.834C>T p.V278= | Silent (SNP) | VAF 17/31 reads (55%) | catalogued as COSV100870326; called by muse, mutect2, varscan2
- MS4A10 | c.48C>T p.L16= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV100382241; called by muse, mutect2, varscan2
- MUC5B | c.8088G>A p.T2696= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as rs970042183; called by muse, mutect2, varscan2
- MYO18B | c.840G>A p.G280= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1252946819, COSV59147358; called by muse, mutect2, varscan2
- NCOR2 | c.6669C>T p.S2223= | Silent (SNP) | VAF 13/37 reads (35%) | catalogued as COSV100657040; called by muse, mutect2, varscan2
- NID2 | c.1674C>T p.I558= | Silent (SNP) | VAF 52/116 reads (45%) | catalogued as rs748259191, COSV53504772; called by muse, mutect2, varscan2
- NOMO1 | c.3468C>T p.I1156= | Silent (SNP) | VAF 47/165 reads (28%) | catalogued as rs374422575; called by muse, mutect2, varscan2
- NRXN3 | c.2475C>T p.S825= (on ENST00000335750 / NM_001330195.2; = p.S452= on NM_004796.6) | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs765527436, COSV59716249; called by muse, mutect2, varscan2
- OR51M1 | c.612C>T p.I204= | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100150176, COSV60784966; called by muse, mutect2, varscan2
- POLL | c.471C>T p.T157= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV100150118; called by muse, mutect2, varscan2
- RAD23B | c.156C>T p.I52= | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs1436643410, COSV100787660; called by muse, mutect2, varscan2
- SIAH3 | c.450C>T p.L150= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV101247770; called by muse, mutect2, varscan2
- SIL1 | c.255C>T p.V85= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99497846; called by muse, mutect2, varscan2
- SLC2A13 | c.1125C>T p.F375= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs773186400, COSV99786192, COSV99786195; called by muse, mutect2, varscan2
- SLC2A14 | c.852C>T p.L284= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1465778984, COSV100533676; called by muse, mutect2, varscan2
- SLC38A11 | c.69C>T p.S23= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV58052265; called by muse, mutect2, varscan2
- SLCO1B3 | c.1605C>T p.F535= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV53932033; called by muse, mutect2, varscan2
- SPEF2 | c.2469G>A p.K823= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs778970768, COSV100606724; called by muse, mutect2, varscan2
- SPTB | c.4983C>T p.I1661= | Silent (SNP) | VAF 40/130 reads (31%) | catalogued as rs779414063, COSV101072014; called by muse, mutect2, varscan2
- SPTBN4 | c.7389G>A p.P2463= | Silent (SNP) | VAF 60/218 reads (28%) | catalogued as rs759812450, COSV52541994; called by muse, mutect2, varscan2
- THSD7B | c.1551C>T p.V517= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99746804; called by muse, mutect2, varscan2
- TRAV6 | c.301C>T p.L101= | Silent (SNP) | VAF 33/105 reads (31%) | called by muse, mutect2, varscan2
- TREML2 | c.645C>A p.P215= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as COSV101530153; called by muse, mutect2, varscan2
- TRIM61 | c.31C>A p.R11= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV100255967; called by muse, mutect2, varscan2
- TRPC4 | c.324C>T p.V108= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs768932261, COSV100156830, COSV59011862; called by muse, mutect2, varscan2
- TTN | c.43020G>A p.T14340= (on ENST00000591111; = p.T6916= on NM_003319.4) | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as rs751428690, COSV59889131; called by muse, mutect2, varscan2
- UBE3C | c.1611T>C p.F537= | Silent (SNP) | VAF 55/101 reads (54%) | catalogued as COSV100779866; called by muse, mutect2, varscan2
- UGT1A8 | c.504C>T p.F168= | Silent (SNP) | VAF 65/184 reads (35%) | catalogued as rs773847275, COSV65078267; called by muse, mutect2, varscan2
- UNC5B | c.690C>T p.I230= | Silent (SNP) | VAF 52/106 reads (49%) | catalogued as rs781650417, COSV58978709; called by muse, mutect2, varscan2
- URI1 | c.1401T>C p.L467= | Silent (SNP) | VAF 29/67 reads (43%) | catalogued as COSV100368909; called by muse, mutect2, varscan2
- MIR205 | n.35C>T | RNA (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- PKHD1 | c.*2C>T | 3'UTR (SNP) | VAF 38/93 reads (41%) | catalogued as COSV100944019; called by muse, mutect2, varscan2
- TTN | c.10360+3878A>G | Intron (SNP) | VAF 27/73 reads (37%) | catalogued as COSV100600865; called by muse, mutect2, varscan2
